Somatic mutation profile of tumor specimen MP2PRT-PAVVWY-TMP1-A (aliquot MP2PRT-PAVVWY-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVVWY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,010 days).
Specimen MP2PRT-PAVVWY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f697b10f-3847-4f98-b6ec-51ec567005d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVVWY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVVWY-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cc83d71-0164-4b8d-827a-e11c51a81ed3

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GARNL3 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs555018373; called by muse, mutect2, varscan2
- PPARGC1A | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 88/459 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370320097; called by muse, mutect2, varscan2
- SLC22A6 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750411183, COSV100842881; called by muse, mutect2, varscan2
- SPATA31E1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 34/598 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.197); catalogued as rs370729196; called by muse, mutect2
- TRPV3 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767538050, COSV100027704, COSV100028221; called by muse, mutect2, varscan2
- PLSCR5 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- RIMS1 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- HPS6 | c.2307G>T p.P769= | Silent (SNP) | VAF 48/336 reads (14%) | called by muse, mutect2, varscan2
- HYDIN | c.3006T>A p.I1002= | Silent (SNP) | VAF 75/213 reads (35%) | called by muse, mutect2, varscan2
- IRS1 | c.2220C>T p.D740= | Silent (SNP) | VAF 92/286 reads (32%) | catalogued as rs1371097714; called by muse, mutect2, varscan2
- KCTD1 | c.426C>T p.C142= | Silent (SNP) | VAF 99/425 reads (23%) | catalogued as rs896053709, COSV58683957; called by muse, mutect2, varscan2
- SETD1B | c.1020C>T p.A340= | Silent (SNP) | VAF 95/290 reads (33%) | catalogued as rs748283451; called by muse, mutect2, varscan2
- SLC22A6 | c.954C>T p.T318= | Silent (SNP) | VAF 22/251 reads (9%) | catalogued as rs1230674861; called by muse, mutect2
